Somatic mutation profile of tumor specimen MMRF_2761_1_BM_CD138pos (aliquot MMRF_2761_1_BM_CD138pos_T1_KHS5U_L15713) from MMRF case MMRF_2761, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.7 years (22,912 days).
Specimen MMRF_2761_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb30ecd2-3a7e-420c-9cdb-4c5596cdfc56.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2761_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2761_1_PB_WBC_C3_KHS5U_L15757; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7533df8-1c8e-4517-ba8c-b6c75dcc76a6

The open-access MAF lists 440 somatic variants for this specimen: 158 protein-altering or splice-affecting, 58 silent, 224 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 141, 3'UTR 112, Silent 58, Intron 49, 5'UTR 37, 5'Flank 12, Nonsense Mutation 9, 3'Flank 9, Splice Site 5, RNA 5, Splice Region 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.2066G>A p.R689Q | Missense Mutation (SNP) | VAF 64/72 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV66706044; called by muse, mutect2, varscan2
- ABI2 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 7/167 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV53694735; called by muse, mutect2
- ACHE | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 26/205 reads (13%) | SIFT tolerated (0.76); PolyPhen benign (0.024); catalogued as rs763331269; called by muse, mutect2, varscan2
- AEBP1 | c.979G>A p.D327N | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.04); catalogued as rs769957543, COSV56256355; called by muse, mutect2, varscan2
- ANKRD39 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.249); catalogued as COSV100561058, COSV59692086; called by muse, mutect2, varscan2
- ATF6B | c.1066C>T p.R356W | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs894885466; called by muse, mutect2
- B3GALT4 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 15/252 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.019); catalogued as COSV65851661; called by muse, mutect2
- B3GNT4 | c.259C>G p.L87V | Missense Mutation (SNP) | VAF 71/260 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as rs972389008, COSV99928087, COSV99928322; called by muse, mutect2, varscan2
- BCL2L12 | c.134G>C p.R45P | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs772990009; called by muse, mutect2, varscan2
- CAPN11 | c.949C>T p.R317W | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs375074381, COSV67236236; called by muse, mutect2
- CARMIL2 | c.1222C>A p.P408T | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.034); catalogued as rs535663690; called by muse, mutect2, varscan2
- CBX8 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53936240; called by muse, mutect2, varscan2
- CCDC181 | c.30G>C p.K10N | Missense Mutation (SNP) | VAF 13/196 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.361); catalogued as COSV63156826; called by muse, mutect2
- CFAP94 | c.1811C>T p.S604F (on ENST00000320267 / NM_001352064.2; = p.S610F on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/262 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs965175661, COSV57235844; called by muse, mutect2
- CFHR1 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 32/333 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.721); catalogued as COSV57627473; called by muse, mutect2, varscan2
- CLMP | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs542828277; called by muse, mutect2
- CPN2 | c.1592C>T p.S531F | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as rs1560281929; called by muse, mutect2, varscan2
- DARS2 | c.1367G>A p.R456Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1397125966; called by muse, mutect2, varscan2
- DNAH10 | c.11413C>G p.Q3805E (on ENST00000409039; = p.Q3744E on NM_207437.3) | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as COSV68990791; called by muse, varscan2
- ELOVL5 | c.65G>C p.R22T | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100439987; called by muse, mutect2, varscan2
- ELP1 | c.2527C>T p.H843Y | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.443); catalogued as COSV65899943; called by muse, mutect2
- ELSPBP1 | c.302C>G p.S101* | Nonsense Mutation (SNP) | VAF 14/46 reads (30%) | catalogued as COSV60414663; called by muse, mutect2, varscan2
- ENPP2 | c.905C>T p.S302L | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as rs1563718147, COSV50012128, COSV99309160; called by muse, mutect2, varscan2
- ERICH1 | c.564C>A p.F188L | Missense Mutation (SNP) | VAF 68/234 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50637327; called by muse, varscan2
- FGD4 | c.2014C>A p.L672I | Missense Mutation (SNP) | VAF 83/166 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.385); catalogued as COSV56783493; called by muse, varscan2
- FLI1 | c.1334C>G p.P445R | Missense Mutation (SNP) | VAF 36/406 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as COSV55646399; called by muse, mutect2
- GLT6D1 | c.14G>C p.R5T | Missense Mutation (SNP) | VAF 12/187 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as COSV100874504, COSV65627590; called by muse, mutect2
- GTF3A | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs757021040; called by muse, mutect2, varscan2
- HIVEP3 | c.5681C>T p.S1894F | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs758530264; called by muse, mutect2, varscan2
- IFITM2 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as rs1367648835; called by muse, mutect2
- IGF2R | c.5576C>T p.S1859L | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV100807570; called by muse, mutect2
- INTS3 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 33/252 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV59680305; called by muse, mutect2, varscan2
- ITFG2 | c.28G>A p.V10M | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as rs753129997; called by muse, mutect2, varscan2
- JUN | c.472G>A p.G158S | Missense Mutation (SNP) | VAF 89/178 reads (50%) | SIFT tolerated (0.97); PolyPhen benign (0.018); catalogued as COSV64665038; called by muse, mutect2, varscan2
- KCNA3 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 21/278 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV63902640; called by muse, mutect2
- KDM2A | c.1941G>C p.E647D | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as rs978269729; called by muse, mutect2, varscan2
- LRP4 | c.5087+1G>A p.X1696_splice | Splice Site (SNP) | VAF 14/118 reads (12%) | catalogued as rs761288117; called by muse, mutect2, varscan2
- LRRC9 | c.3754G>T p.E1252* | Nonsense Mutation (SNP) | VAF 31/205 reads (15%) | catalogued as COSV54292107; called by muse, mutect2, varscan2
- LY6K | c.156C>A p.F52L | Missense Mutation (SNP) | VAF 15/190 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); catalogued as COSV52832015; called by muse, mutect2
- MAGEB16 | c.723C>A p.F241L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.082); catalogued as rs1379447911, COSV101303318; called by muse, mutect2, varscan2
- MAGEB18 | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 81/84 reads (96%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs756040996; called by muse, mutect2, varscan2
- MDN1 | c.16006G>C p.E5336Q | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749304079, COSV65533580; called by muse, mutect2, varscan2
- MEGF11 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.755); catalogued as COSV56552311, COSV56558185; called by muse, mutect2
- NBPF3 | c.1188C>G p.D396E | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.425); catalogued as rs773943645; called by muse, mutect2, varscan2
- NOTCH4 | c.5929G>A p.E1977K | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.572); catalogued as rs1239036035, COSV66679314, COSV66679913; called by muse, mutect2
- NOTCH4 | c.5378G>A p.R1793Q | Missense Mutation (SNP) | VAF 35/222 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1210630301, COSV66679301, COSV66683180; called by muse, mutect2, varscan2
- NUDT5 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58502467; called by muse, varscan2
- PCDH18 | c.2507C>G p.S836* | Nonsense Mutation (SNP) | VAF 7/206 reads (3%) | catalogued as COSV61268547; called by muse, mutect2
- PDE7A | c.298G>A p.E100K (on ENST00000401827 / NM_001242318.3; = p.E74K on NM_002603.4) | Missense Mutation (SNP) | VAF 70/144 reads (49%) | SIFT tolerated (0.37); PolyPhen benign (0.138); catalogued as rs973314146; called by muse, varscan2
- PHACTR3 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 13/199 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as rs1298287124; called by muse, mutect2
- PRKRA | c.396+2T>A p.X132_splice | Splice Site (SNP) | VAF 42/131 reads (32%) | catalogued as rs202008461; called by muse, mutect2, varscan2
- PTPN2 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 7/167 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs1254988153; called by muse, mutect2
- RGP1 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1266550854, COSV65240505; called by muse, mutect2, varscan2
- RYR3 | c.9496G>A p.E3166K (on ENST00000389232; = p.E3167K on NM_001036.6) | Missense Mutation (SNP) | VAF 23/334 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.335); catalogued as COSV66811367; called by muse, mutect2
- SETD2 | c.5833G>A p.E1945K | Missense Mutation (SNP) | VAF 30/224 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV104396428; called by muse, mutect2, varscan2
- SI | c.4511G>A p.R1504Q | Missense Mutation (SNP) | VAF 73/158 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs569447227, COSV52266598, COSV52293282; called by muse, mutect2, varscan2
- SLIT3 | c.2210G>A p.R737Q | Missense Mutation (SNP) | VAF 17/192 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1230535907, COSV60622505; called by muse, mutect2
- SNRNP200 | c.3859C>T p.R1287W | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1004264460; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TEX10 | c.1793G>A p.R598Q | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1434850976, COSV66517007, COSV66518841; called by mutect2, varscan2
- TRIM23 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 37/285 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.346); catalogued as COSV51552758; called by muse, mutect2, varscan2
- TTC6 | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.702); catalogued as rs1294709312; called by muse, mutect2, varscan2
- ZDBF2 | c.6395C>G p.S2132* | Nonsense Mutation (SNP) | VAF 19/165 reads (12%) | catalogued as COSV99056659; called by muse, mutect2, varscan2
- ZNF211 | c.760G>A p.E254K (on ENST00000347302 / NM_198855.4; = p.E267K on NM_006385.5) | Missense Mutation (SNP) | VAF 71/216 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.029); catalogued as rs1358055457; called by muse, mutect2, varscan2
- ZNF217 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.071); catalogued as rs1364868960, COSV100184302, COSV56598347; called by muse, mutect2, varscan2
- ABCC11 | c.2463C>G p.I821M | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.217); called by muse, mutect2
- AGAP2 | c.2858-6C>A | Splice Region (SNP) | VAF 8/202 reads (4%) | called by muse, mutect2
- AHDC1 | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- AKAP5 | c.788C>G p.S263C | Missense Mutation (SNP) | VAF 36/392 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2
- ANKIB1 | c.203G>C p.R68T | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- ANKRA2 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.971); called by muse, mutect2
- ARL14EP | c.87G>C p.K29N | Missense Mutation (SNP) | VAF 50/184 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- ASXL1 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ATP8A1 | c.162C>T p.V54= | Splice Region (SNP) | VAF 16/290 reads (6%) | called by muse, mutect2
- BRCA1 | c.3205C>G p.Q1069E | Missense Mutation (SNP) | VAF 20/356 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.271); called by muse, mutect2
- C1orf112 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.194); called by muse, mutect2
- CACNA2D3 | c.2191C>G p.R731G | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CARMIL2 | c.3857C>T p.S1286F | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.735); called by mutect2, varscan2
- CARNMT1 | c.599C>G p.S200C | Missense Mutation (SNP) | VAF 30/306 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2
- CDAN1 | c.3271G>A p.A1091T | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.487); called by muse, mutect2
- CDCA2 | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- CEP97 | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- CNTNAP1 | c.3275C>G p.S1092C | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); called by muse, mutect2
- DCAF4 | c.632C>A p.T211K | Missense Mutation (SNP) | VAF 18/279 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.177); called by muse, mutect2
- DCPS | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EIF2AK4 | c.2890G>A p.E964K | Missense Mutation (SNP) | VAF 77/273 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ERMP1 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FAM81A | c.982G>C p.G328R | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2
- FANCA | c.3077C>G p.A1026G | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FBXO38 | c.70G>C p.D24H | Missense Mutation (SNP) | VAF 24/225 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.371); called by muse, mutect2
- FER1L6 | c.779C>G p.S260* | Nonsense Mutation (SNP) | VAF 13/101 reads (13%) | called by muse, mutect2, varscan2
- GASK1B | c.1234C>G p.L412V | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GCNT3 | c.277A>C p.K93Q | Missense Mutation (SNP) | VAF 61/187 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- GDF2 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.018); called by muse, mutect2
- GLS2 | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 29/227 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- GLT6D1 | c.15A>T p.R5S | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.037); called by muse, mutect2
- GOLM2 | c.983C>G p.S328* | Nonsense Mutation (SNP) | VAF 47/171 reads (27%) | called by muse, mutect2, varscan2
- GREB1 | c.956A>G p.E319G | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT tolerated (1); PolyPhen possibly damaging (0.889); called by muse, mutect2
- HEATR5B | c.2015G>A p.R672K | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.767); called by muse, varscan2
- HPS1 | c.1279G>A p.D427N | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- HRC | c.1892C>A p.S631Y | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- HS2ST1 | c.49G>T p.V17L | Missense Mutation (SNP) | VAF 15/203 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2
- IGHA1 | c.504G>C p.K168N | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.172); called by mutect2, varscan2
- IGHV1-69D | c.236A>T p.Y79F | Missense Mutation (SNP) | VAF 132/191 reads (69%) | SIFT deleterious (0.03); PolyPhen benign (0.137); called by muse, varscan2
- IGHV1-69D | c.217A>T p.I73F | Missense Mutation (SNP) | VAF 128/192 reads (67%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, varscan2
- IGHV2-70D | c.218A>G p.D73G | Missense Mutation (SNP) | VAF 84/98 reads (86%) | SIFT tolerated (0.29); PolyPhen benign (0.162); called by muse, varscan2
- IGSF9B | c.893C>G p.S298W | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- IL26 | c.286C>A p.Q96K | Missense Mutation (SNP) | VAF 23/249 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2
- KDM2A | c.1766G>C p.R589T | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- KLF13 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- KLF9 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- KMT2A | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- KMT2D | c.15916G>A p.E5306K | Missense Mutation (SNP) | VAF 12/302 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LGR4 | c.258-1G>C p.X86_splice | Splice Site (SNP) | VAF 11/98 reads (11%) | called by mutect2, varscan2
- LMBRD1 | c.547G>T p.V183F (on ENST00000649011; = p.V161F on NM_018368.4) | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- LRRIQ4 | c.1003G>C p.D335H | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MADD | c.1870G>C p.D624H | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MAFF | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- MAST4 | c.6760C>T p.P2254S (on ENST00000403625 / NM_001164664.2; = p.P2065S on NM_015183.3) | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MCF2 | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.091); called by muse, mutect2
- MICAL2 | c.4429G>A p.A1477T | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC17 | c.8315C>T p.S2772L | Missense Mutation (SNP) | VAF 46/492 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); called by muse, mutect2
- MYO1F | c.749G>A p.R250K | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MYO9A | c.6445G>C p.E2149Q | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.752); called by muse, mutect2
- NALCN | c.1681G>A p.D561N | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.115); called by muse, mutect2
- NEO1 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.019); called by muse, mutect2
- NIBAN3 | c.925C>T p.H309Y | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- NOL8 | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.011); called by mutect2, varscan2
- NRCAM | c.3560T>C p.V1187A (on ENST00000379028 / NM_001371124.1; = p.V1066A on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 83/184 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- NYX | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PAXBP1 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.402); called by muse, mutect2
- PDE7A | c.409G>A p.D137N (on ENST00000401827 / NM_001242318.3; = p.D111N on NM_002603.4) | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, varscan2
- PFKM | c.938G>A p.G313D | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- PICK1 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PKHD1L1 | c.2955G>A p.W985* | Nonsense Mutation (SNP) | VAF 24/95 reads (25%) | called by muse, mutect2, varscan2
- PPFIA3 | c.2644G>A p.E882K | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- PPP2R2A | c.973-1G>A p.X325_splice | Splice Site (SNP) | VAF 9/83 reads (11%) | called by muse, mutect2, varscan2
- PRICKLE2 | c.424G>A p.E142K (on ENST00000295902; = p.E86K on NM_198859.4) | Missense Mutation (SNP) | VAF 76/194 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PTGFR | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 36/366 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.082); called by muse, mutect2
- PTK7 | c.1932C>G p.F644L | Missense Mutation (SNP) | VAF 16/302 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0.006); called by muse, mutect2
- RASA1 | c.310G>A p.G104S | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated, low confidence (0.59); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- RNF130 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 58/183 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- S100PBP | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 25/223 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- SCGB1C2 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 3/59 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.443); called by muse, mutect2
- SCN3A | c.1053C>G p.I351M | Missense Mutation (SNP) | VAF 72/232 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- SETD1A | c.2164C>G p.Q722E | Missense Mutation (SNP) | VAF 68/165 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.177); called by muse, varscan2
- SLC19A2 | c.634C>T p.Q212* | Nonsense Mutation (SNP) | VAF 19/98 reads (19%) | called by mutect2, varscan2
- SNAPC1 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- STAT6 | c.1956-4C>G | Splice Region (SNP) | VAF 14/176 reads (8%) | called by muse, mutect2
- TAOK3 | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 89/200 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TLN2 | c.6919G>C p.E2307Q | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRAF3IP2 | c.790C>T p.L264F | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.013); called by muse, mutect2
- TRIM66 | c.2347C>T p.P783S | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- TXK | c.447-1G>A p.X149_splice | Splice Site (SNP) | VAF 8/59 reads (14%) | called by mutect2, varscan2
- ZC3H14 | c.613T>C p.Y205H | Missense Mutation (SNP) | VAF 42/366 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ZER1 | c.1930G>C p.D644H | Missense Mutation (SNP) | VAF 6/145 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZHX2 | c.2308G>C p.D770H | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.009); called by muse, varscan2
- ZNF337 | c.1054G>T p.E352* | Nonsense Mutation (SNP) | VAF 20/246 reads (8%) | called by muse, mutect2
- ZNF891 | c.1229G>A p.G410E | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AC092143.1 | c.1497C>T p.I499= | Silent (SNP) | VAF 5/79 reads (6%) | catalogued as COSV59247844; called by muse, mutect2
- ADAMTS15 | c.2256G>A p.V752= | Silent (SNP) | VAF 12/176 reads (7%) | catalogued as rs1284099128, COSV54507318; called by muse, mutect2
- AMPH | c.1590C>T p.L530= | Silent (SNP) | VAF 62/170 reads (36%) | catalogued as rs201328417, COSV100340349, COSV57736176; called by mutect2, varscan2
- ANKRD10 | c.531C>A p.L177= | Silent (SNP) | VAF 8/224 reads (4%) | called by muse, mutect2
- ANKRD62 | c.2385G>A p.K795= | Silent (SNP) | VAF 17/246 reads (7%) | called by muse, mutect2
- ARHGAP18 | c.366C>G p.L122= | Silent (SNP) | VAF 34/283 reads (12%) | catalogued as rs1405576064; called by muse, mutect2, varscan2
- ATP13A4 | c.2118C>T p.L706= | Silent (SNP) | VAF 27/126 reads (21%) | catalogued as rs1560193896; called by muse, mutect2, varscan2
- BCL2 | c.240C>T p.A80= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as rs1217931931; called by muse, mutect2, varscan2
- BPIFB4 | c.696G>A p.L232= | Silent (SNP) | VAF 17/131 reads (13%) | called by muse, mutect2, varscan2
- C17orf49 | c.396G>A p.K132= | Silent (SNP) | VAF 30/70 reads (43%) | called by muse, mutect2, varscan2
- CASP9 | c.463C>T p.L155= | Silent (SNP) | VAF 15/128 reads (12%) | called by muse, mutect2, varscan2
- CD22 | c.99C>T p.Y33= | Silent (SNP) | VAF 42/147 reads (29%) | catalogued as rs183001623, COSV50055741; called by muse, mutect2, varscan2
- CRAMP1 | c.3318C>T p.I1106= | Silent (SNP) | VAF 44/154 reads (29%) | called by muse, mutect2, varscan2
- CROT | c.783G>A p.E261= | Silent (SNP) | VAF 15/183 reads (8%) | catalogued as COSV58974695; called by muse, mutect2
- CRYBG3 | c.1785T>C p.S595= | Silent (SNP) | VAF 57/130 reads (44%) | called by muse, mutect2, varscan2
- CUX2 | c.2265G>A p.A755= | Silent (SNP) | VAF 15/252 reads (6%) | catalogued as rs1426000034; called by muse, mutect2
- DDX60 | c.1062C>T p.F354= | Silent (SNP) | VAF 29/94 reads (31%) | called by muse, mutect2, varscan2
- DOCK5 | c.3084C>T p.L1028= | Silent (SNP) | VAF 50/164 reads (30%) | called by muse, varscan2
- FAAH2 | c.978C>T p.L326= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV66505494; called by muse, mutect2, varscan2
- FGD4 | c.528C>T p.T176= | Silent (SNP) | VAF 76/154 reads (49%) | called by muse, varscan2
- FLT3LG | c.366C>T p.F122= | Silent (SNP) | VAF 32/74 reads (43%) | catalogued as rs1380556821; called by muse, mutect2, varscan2
- FMNL2 | c.660T>C p.D220= | Silent (SNP) | VAF 42/77 reads (55%) | called by muse, mutect2, varscan2
- FOXO1 | c.1779C>T p.L593= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as rs775906686, COSV65427121; called by muse, mutect2
- FSD1 | c.402G>A p.L134= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV55694980; called by muse, mutect2, varscan2
- GNPNAT1 | c.42C>T p.L14= | Silent (SNP) | VAF 18/100 reads (18%) | catalogued as COSV53592497; called by muse, mutect2, varscan2
- GRB14 | c.1425C>T p.F475= | Silent (SNP) | VAF 9/88 reads (10%) | catalogued as rs138769540; called by muse, mutect2, varscan2
- H2BC5 | c.84G>A p.K28= | Silent (SNP) | VAF 97/269 reads (36%) | catalogued as rs1281090262; called by muse, mutect2, varscan2
- HESX1 | c.309G>A p.L103= | Silent (SNP) | VAF 25/82 reads (30%) | called by muse, mutect2
- IGHV2-70D | c.168C>T p.S56= | Silent (SNP) | VAF 66/76 reads (87%) | catalogued as rs1233195687; called by muse, varscan2
- LMF1 | c.1161G>A p.L387= | Silent (SNP) | VAF 11/198 reads (6%) | called by muse, mutect2
- LRIT2 | c.687G>A p.L229= | Silent (SNP) | VAF 16/206 reads (8%) | called by muse, mutect2
- MAPK4 | c.1491C>G p.V497= | Silent (SNP) | VAF 47/102 reads (46%) | catalogued as rs1197491001; called by muse, mutect2, varscan2
- MCEMP1 | c.231C>T p.C77= | Silent (SNP) | VAF 34/82 reads (41%) | catalogued as rs1462845196; called by muse, mutect2, varscan2
- MIPEP | c.1773C>G p.P591= | Silent (SNP) | VAF 7/75 reads (9%) | called by muse, mutect2
- MYO1B | c.1533G>A p.R511= | Silent (SNP) | VAF 17/108 reads (16%) | catalogued as rs1304439794; called by muse, mutect2, varscan2
- NDOR1 | c.30C>T p.F10= | Silent (SNP) | VAF 18/169 reads (11%) | called by muse, mutect2, varscan2
- PCDH12 | c.432C>T p.I144= | Silent (SNP) | VAF 18/294 reads (6%) | called by muse, mutect2
- PDZRN3 | c.3060G>A p.L1020= | Silent (SNP) | VAF 83/267 reads (31%) | catalogued as rs538101633; called by muse, mutect2, varscan2
- PLXNA2 | c.3492G>A p.L1164= | Silent (SNP) | VAF 29/102 reads (28%) | called by muse, mutect2, varscan2
- PNPLA8 | c.1335C>G p.L445= | Silent (SNP) | VAF 55/239 reads (23%) | catalogued as rs773951279, COSV57552351; called by muse, mutect2, varscan2
- PSPC1 | c.474G>A p.L158= | Silent (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2, varscan2
- RABEP2 | c.1575G>A p.Q525= | Silent (SNP) | VAF 44/90 reads (49%) | catalogued as rs1027858640; called by muse, mutect2, varscan2
- RHOBTB2 | c.435C>T p.R145= | Silent (SNP) | VAF 91/197 reads (46%) | called by muse, mutect2, varscan2
- RPS29 | c.69C>T p.V23= | Silent (SNP) | VAF 17/181 reads (9%) | catalogued as rs1257250180; called by muse, mutect2
- SLC6A4 | c.1506C>G p.L502= | Silent (SNP) | VAF 16/116 reads (14%) | catalogued as COSV99911388; called by mutect2, varscan2
- SOX1 | c.645G>A p.Q215= | Silent (SNP) | VAF 2/8 reads (25%) | called by muse, mutect2
- STARD9 | c.13533C>T p.F4511= | Silent (SNP) | VAF 15/94 reads (16%) | called by muse, mutect2, varscan2
- STRN4 | c.1239C>G p.L413= | Silent (SNP) | VAF 49/215 reads (23%) | called by muse, mutect2, varscan2
- TFR2 | c.957G>A p.V319= | Silent (SNP) | VAF 47/190 reads (25%) | called by muse, mutect2, varscan2
- TMEM102 | c.1275G>A p.A425= | Silent (SNP) | VAF 12/104 reads (12%) | called by muse, mutect2, varscan2
- TTC7A | c.1455C>T p.F485= | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as rs747356513, COSV55409969; called by mutect2, varscan2
- VPS37D | c.699C>A p.L233= | Silent (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
- WDR18 | c.349C>T p.L117= | Silent (SNP) | VAF 55/189 reads (29%) | called by muse, mutect2, varscan2
- ZGLP1 | c.678C>A p.L226= | Silent (SNP) | VAF 25/239 reads (10%) | catalogued as COSV67059701; called by muse, mutect2, varscan2
- ZHX2 | c.2388G>A p.V796= | Silent (SNP) | VAF 44/162 reads (27%) | catalogued as rs768004784; called by muse, varscan2
- ZNF480 | c.522C>T p.V174= | Silent (SNP) | VAF 94/369 reads (25%) | catalogued as rs778993253; called by muse, mutect2, varscan2
- ZNF597 | c.615C>A p.I205= | Silent (SNP) | VAF 30/272 reads (11%) | called by muse, mutect2, varscan2
- ZNF689 | c.78G>A p.P26= | Silent (SNP) | VAF 13/140 reads (9%) | catalogued as COSV54910061; called by muse, mutect2
- AC005220.1 | chr20:53938478 C>T | 5'Flank (SNP) | VAF 37/96 reads (39%) | called by muse, mutect2, varscan2
- AC116366.2 | c.-638+11283C>T | Intron (SNP) | VAF 28/109 reads (26%) | called by muse, mutect2, varscan2
- ACKR1 | c.22-103C>G | Intron (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- ADAM12 | c.*692G>C | 3'UTR (SNP) | VAF 65/194 reads (34%) | called by muse, mutect2, varscan2
- ADAMTSL1 | c.601+149G>A | Intron (SNP) | VAF 39/91 reads (43%) | called by muse, mutect2, varscan2
- ADGRA1 | c.*690G>C | 3'UTR (SNP) | VAF 8/119 reads (7%) | called by muse, mutect2
- AGO4 | c.2477+28C>G | Intron (SNP) | VAF 8/43 reads (19%) | called by muse, mutect2, varscan2
- AKTIP | c.313+10G>C | Intron (SNP) | VAF 22/149 reads (15%) | catalogued as rs766375002; called by muse, mutect2, varscan2
- ANKLE2 | c.182-2118G>A | Intron (SNP) | VAF 63/131 reads (48%) | catalogued as rs773984156; called by muse, mutect2, varscan2
- AREL1 | c.*467C>T | 3'UTR (SNP) | VAF 18/270 reads (7%) | called by muse, mutect2
- ARFGEF3 | c.*997G>T | 3'UTR (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2, varscan2
- ARHGAP42 | c.*4827G>A | 3'UTR (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- ARSJ | c.-224G>A | 5'UTR (SNP) | VAF 15/128 reads (12%) | catalogued as rs1164202559; called by muse, mutect2, varscan2
- ASB2 | c.168-1013C>T | Intron (SNP) | VAF 21/196 reads (11%) | called by muse, mutect2, varscan2
- ASCC3 | c.241+7595T>C | Intron (SNP) | VAF 6/79 reads (8%) | called by muse, mutect2
- ASIC2 | c.556-179734G>C | Intron (SNP) | VAF 98/230 reads (43%) | catalogued as COSV99859222; called by muse, mutect2, varscan2
- ATP23 | c.-115C>T | 5'UTR (SNP) | VAF 13/46 reads (28%) | called by muse, mutect2, varscan2
- B4GALNT1 | c.1003-87G>T | Intron (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- BAIAP2L1 | c.-169G>C | 5'UTR (SNP) | VAF 33/91 reads (36%) | catalogued as rs965543982; called by muse, mutect2, varscan2
- BAZ1A | c.113+66C>T | Intron (SNP) | VAF 30/68 reads (44%) | called by muse, mutect2
- BCL9 | c.*572C>T | 3'UTR (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- BMERB1 | c.*433C>G | 3'UTR (SNP) | VAF 17/252 reads (7%) | called by muse, mutect2
- BMF | c.*3565G>A | 3'UTR (SNP) | VAF 38/119 reads (32%) | called by muse, mutect2, varscan2
- BPNT2 | c.*4270C>T | 3'UTR (SNP) | VAF 32/116 reads (28%) | called by muse, mutect2, varscan2
- C15orf62 | c.*731C>G | 3'UTR (SNP) | VAF 12/90 reads (13%) | called by mutect2, varscan2
- C21orf58 | c.-763G>A | 5'UTR (SNP) | VAF 10/123 reads (8%) | called by muse, mutect2
- C4orf33 | c.-692G>A | 5'UTR (SNP) | VAF 12/105 reads (11%) | called by muse, mutect2, varscan2
- C5orf49 | c.-44C>T | 5'UTR (SNP) | VAF 4/44 reads (9%) | catalogued as rs1287135658; called by muse, mutect2
- C6orf223 | n.659G>T | RNA (SNP) | VAF 20/268 reads (7%) | catalogued as rs1391841732; called by muse, mutect2
- C8G | c.595+36G>A | Intron (SNP) | VAF 17/111 reads (15%) | catalogued as rs765377282; called by muse, mutect2, varscan2
- C9orf40 | c.-254C>A | 5'UTR (SNP) | VAF 33/110 reads (30%) | called by muse, mutect2, varscan2
- CACNA1E | c.*5366G>A | 3'UTR (SNP) | VAF 4/74 reads (5%) | called by muse, mutect2
- CACNA1E | c.*6551G>A | 3'UTR (SNP) | VAF 6/118 reads (5%) | called by muse, mutect2
- CAMLG | c.172+11C>T | Intron (SNP) | VAF 8/164 reads (5%) | called by muse, mutect2
- CCND1 | c.*1443C>A | 3'UTR (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
- CCR2 | c.*384G>C | 3'UTR (SNP) | VAF 27/56 reads (48%) | called by muse, mutect2, varscan2
- CDH6 | c.*4522G>A | 3'UTR (SNP) | VAF 12/113 reads (11%) | catalogued as rs1344386046; called by muse, mutect2, varscan2
- CEP41 | c.98-4348C>T | Intron (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
- CHMP7 | c.*1130C>T | 3'UTR (SNP) | VAF 39/117 reads (33%) | called by muse, mutect2, varscan2
- CISH | c.-36G>A | 5'UTR (SNP) | VAF 9/85 reads (11%) | catalogued as rs781167277; called by muse, mutect2
- CMPK2 | c.*484C>T | 3'UTR (SNP) | VAF 42/136 reads (31%) | called by muse, varscan2
- COL11A2 | c.-40G>A | 5'UTR (SNP) | VAF 18/66 reads (27%) | catalogued as COSV59502859; called by muse, mutect2, varscan2
- CTF1 | c.*95C>T | 3'UTR (SNP) | VAF 26/95 reads (27%) | catalogued as rs576400812; called by muse, mutect2, varscan2
- CTNS | c.*869G>A | 3'UTR (SNP) | VAF 17/275 reads (6%) | catalogued as rs1023869498; called by muse, mutect2
- CXorf38 | c.217-62G>A | Intron (SNP) | VAF 37/55 reads (67%) | called by muse, mutect2, varscan2
- DACT3 | c.500-1016G>C | Intron (SNP) | VAF 28/198 reads (14%) | called by muse, mutect2, varscan2
- DBNL | c.*8295T>A | 3'UTR (SNP) | VAF 54/116 reads (47%) | called by muse, mutect2, varscan2
- DEPDC1B | c.*286C>T | 3'UTR (SNP) | VAF 17/155 reads (11%) | called by mutect2, varscan2
- DESI2 | c.*2914G>C | 3'UTR (SNP) | VAF 52/101 reads (51%) | called by muse, mutect2, varscan2
- DIO2 | c.*3331C>A | 3'UTR (SNP) | VAF 8/105 reads (8%) | called by muse, mutect2
- DNASE1 | chr16:3658331 G>C | 3'Flank (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- DOK3 | chr5:177503311 C>T | 3'Flank (SNP) | VAF 12/210 reads (6%) | called by muse, mutect2
- DOK3 | chr5:177503446 C>G | 3'Flank (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- DSCAM | c.*973G>A | 3'UTR (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2, varscan2
- E2F4 | c.-1G>C | 5'UTR (SNP) | VAF 10/24 reads (42%) | called by muse, mutect2, varscan2
- EGF | c.*178C>T | 3'UTR (SNP) | VAF 27/65 reads (42%) | called by muse, mutect2, varscan2
- ENTPD4 | chr8:23425073 G>A | 3'Flank (SNP) | VAF 40/222 reads (18%) | called by muse, mutect2, varscan2
- ENY2 | c.-98G>A | 5'UTR (SNP) | VAF 72/140 reads (51%) | catalogued as COSV53460665; called by muse, mutect2, varscan2
- EYA4 | c.1757-122G>C | Intron (SNP) | VAF 10/98 reads (10%) | catalogued as COSV100765334; called by muse, mutect2
- F11 | c.219-69G>A | Intron (SNP) | VAF 11/36 reads (31%) | called by muse, mutect2, varscan2
- FAM118A | c.522+787C>T | Intron (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2, varscan2
- FANCE | c.-52G>A | 5'UTR (SNP) | VAF 14/61 reads (23%) | called by mutect2, varscan2
- FAT4 | c.*457G>A | 3'UTR (SNP) | VAF 7/93 reads (8%) | called by muse, mutect2
- FBXW7 | c.502-2583G>A | Intron (SNP) | VAF 46/146 reads (32%) | catalogued as rs1292428514, COSV55916399; called by muse, mutect2, varscan2
- FERMT3 | c.1558-137C>G | Intron (SNP) | VAF 3/22 reads (14%) | catalogued as rs1489332529; called by muse, mutect2
- FHL2 | c.-76+39G>T | Intron (SNP) | VAF 21/178 reads (12%) | catalogued as COSV100363087; called by muse, mutect2, varscan2
- FKBP3 | c.-296A>G | 5'UTR (SNP) | VAF 60/142 reads (42%) | called by muse, varscan2
- FOXA1 | c.*758G>A | 3'UTR (SNP) | VAF 7/98 reads (7%) | called by muse, mutect2
- FSHB | c.*5C>T | 3'UTR (SNP) | VAF 22/224 reads (10%) | called by muse, varscan2
- GABRG3 | c.*245G>A | 3'UTR (SNP) | VAF 24/84 reads (29%) | called by muse, mutect2, varscan2
- GALNT17 | c.*1200C>T | 3'UTR (SNP) | VAF 29/244 reads (12%) | called by muse, mutect2, varscan2
- GBP5 | chr1:89271195 G>A | 5'Flank (SNP) | VAF 7/162 reads (4%) | catalogued as rs1425503369; called by muse, mutect2
- GCLC | c.759+871C>G | Intron (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- GCM1 | c.*34C>G | 3'UTR (SNP) | VAF 10/142 reads (7%) | called by muse, mutect2
- GLP1R | c.*380G>A | 3'UTR (SNP) | VAF 58/154 reads (38%) | catalogued as rs1039494829; called by muse, mutect2, varscan2
- GNAZ | c.*433G>A | 3'UTR (SNP) | VAF 36/68 reads (53%) | catalogued as rs895673038; called by muse, mutect2, varscan2
- GOLPH3 | c.*928A>T | 3'UTR (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- GPR150 | c.-151G>A | 5'UTR (SNP) | VAF 32/112 reads (29%) | called by muse, mutect2, varscan2
- GPRC5A | c.*3310C>G | 3'UTR (SNP) | VAF 7/40 reads (18%) | called by muse, mutect2, varscan2
- GSTM5 | c.*443T>C | 3'UTR (SNP) | VAF 54/444 reads (12%) | called by muse, varscan2
- H2AC14 | c.*6G>A | 3'UTR (SNP) | VAF 42/401 reads (10%) | catalogued as rs760271262; called by muse, mutect2, varscan2
- H2AC8 | c.*41G>A | 3'UTR (SNP) | VAF 76/336 reads (23%) | catalogued as COSV55126619; called by muse, mutect2, varscan2
- H2AJ | chr12:14776458 G>T | 3'Flank (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- H2BC9 | c.*33C>T | 3'UTR (SNP) | VAF 107/301 reads (36%) | catalogued as COSV100706780; called by muse, mutect2, varscan2
- H3-2 | c.*104C>T | 3'UTR (SNP) | VAF 52/184 reads (28%) | called by muse, mutect2, varscan2
- HEBP1 | chr12:13000787 G>A | 5'Flank (SNP) | VAF 16/28 reads (57%) | called by mutect2, varscan2
- HEPACAM | c.*97G>T | 3'UTR (SNP) | VAF 8/16 reads (50%) | catalogued as rs890169606; called by muse, mutect2
- HMX2 | c.*468G>A | 3'UTR (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2, varscan2
- HPCA | c.*350C>A | 3'UTR (SNP) | VAF 14/150 reads (9%) | called by muse, mutect2
- HPS3 | c.-10G>A | 5'UTR (SNP) | VAF 10/78 reads (13%) | catalogued as rs1235569717, COSV56058321; called by mutect2, varscan2
- HS3ST1 | c.*818C>T | 3'UTR (SNP) | VAF 33/141 reads (23%) | catalogued as rs1297085585; called by muse, mutect2, varscan2
- HSD3B1 | c.145+135G>C | Intron (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
- HUS1 | c.*1293G>A | 3'UTR (SNP) | VAF 15/166 reads (9%) | called by muse, mutect2
- HYDIN | c.7158+2321G>T | Intron (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- IER5L | c.-178G>A | 5'UTR (SNP) | VAF 42/138 reads (30%) | called by muse, mutect2, varscan2
- IFIH1 | chr2:162319234 G>A | 5'Flank (SNP) | VAF 6/74 reads (8%) | catalogued as rs987834717; called by muse, mutect2
- IFNLR1 | c.*1522C>G | 3'UTR (SNP) | VAF 59/126 reads (47%) | called by muse, mutect2, varscan2
- IL1RAP | c.*656T>A | 3'UTR (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- INTS6L | c.-316C>T | 5'UTR (SNP) | VAF 11/19 reads (58%) | called by muse, mutect2, varscan2
- IRAK3 | c.*4318C>T | 3'UTR (SNP) | VAF 32/144 reads (22%) | called by muse, varscan2
- ITPR2 | c.-159G>A | 5'UTR (SNP) | VAF 28/58 reads (48%) | called by muse, mutect2
- ITSN1 | c.*11043C>T | 3'UTR (SNP) | VAF 20/142 reads (14%) | called by muse, mutect2, varscan2
- KCNA3 | c.-114C>T | 5'UTR (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2, varscan2
- KCTD1 | c.-15-46023G>A | Intron (SNP) | VAF 20/276 reads (7%) | called by muse, mutect2
- KIAA1958 | c.*7204G>T | 3'UTR (SNP) | VAF 8/60 reads (13%) | called by mutect2, varscan2
- KIF1A | c.*2649C>G | 3'UTR (SNP) | VAF 100/214 reads (47%) | called by muse, mutect2, varscan2
- KIF1A | c.*187G>A | 3'UTR (SNP) | VAF 32/71 reads (45%) | called by muse, mutect2, varscan2
- KRT31 | c.-40C>G | 5'UTR (SNP) | VAF 6/130 reads (5%) | called by muse, mutect2
- KRTAP12-1 | c.*136G>C | 3'UTR (SNP) | VAF 40/144 reads (28%) | called by muse, mutect2, varscan2
- LMBRD2 | c.*321G>C | 3'UTR (SNP) | VAF 11/93 reads (12%) | called by muse, mutect2, varscan2
- LY6K | c.*854C>T | 3'UTR (SNP) | VAF 6/71 reads (8%) | called by muse, mutect2
- MBLAC2 | c.454+776C>T | Intron (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
- MCU | c.150+712C>T | Intron (SNP) | VAF 33/90 reads (37%) | called by muse, mutect2, varscan2
- MEF2A | c.*3342C>G | 3'UTR (SNP) | VAF 7/85 reads (8%) | catalogued as rs1410847515; called by muse, mutect2
- MEIS1 | c.*873C>T | 3'UTR (SNP) | VAF 16/90 reads (18%) | catalogued as rs1216717636; called by muse, mutect2, varscan2
- MFSD4B | c.-307C>T | 5'UTR (SNP) | VAF 67/198 reads (34%) | called by muse, mutect2, varscan2
- MIR3155A | n.2C>T | RNA (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2, varscan2
- MOB1B | c.*2541G>A | 3'UTR (SNP) | VAF 39/131 reads (30%) | catalogued as COSV58674925; called by muse, mutect2, varscan2
- MPP7 | c.*618G>C | 3'UTR (SNP) | VAF 7/119 reads (6%) | called by muse, mutect2
- MTHFD1 | c.-44C>T | 5'UTR (SNP) | VAF 40/124 reads (32%) | called by muse, mutect2, varscan2
- MYB | c.*717G>C | 3'UTR (SNP) | VAF 22/74 reads (30%) | called by muse, mutect2, varscan2
- MYL5 | chr4:674263 C>T | 5'Flank (SNP) | VAF 23/229 reads (10%) | catalogued as rs746387456; called by muse, mutect2, varscan2
- NCLN | c.-62G>A | 5'UTR (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- NEK9 | c.*1312C>T | 3'UTR (SNP) | VAF 13/124 reads (10%) | called by muse, mutect2, varscan2
- NHLRC4 | c.-591G>C | 5'UTR (SNP) | VAF 9/80 reads (11%) | called by muse, mutect2, varscan2
- NKX6-3 | c.*805G>A | 3'UTR (SNP) | VAF 19/208 reads (9%) | catalogued as rs962264418; called by muse, mutect2
- NMNAT2 | c.*3833G>A | 3'UTR (SNP) | VAF 27/90 reads (30%) | called by muse, mutect2, varscan2
- NPR3 | c.*1888C>T | 3'UTR (SNP) | VAF 5/99 reads (5%) | called by muse, mutect2
- NRXN1 | c.820+126C>G | Intron (SNP) | VAF 2/10 reads (20%) | called by muse, mutect2
- NUBP2 | c.600+28G>A | Intron (SNP) | VAF 7/199 reads (4%) | catalogued as rs1449407086; called by muse, mutect2
- NUDT16 | c.*3433C>T | 3'UTR (SNP) | VAF 59/195 reads (30%) | called by muse, mutect2, varscan2
- NUDT4 | chr12:93377738 C>T | 5'Flank (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2, varscan2
- NUDT4 | c.*3874C>G | 3'UTR (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2
- OAF | c.*1045A>G | 3'UTR (SNP) | VAF 7/159 reads (4%) | called by muse, mutect2
- ODF2L | c.*253C>T | 3'UTR (SNP) | VAF 17/128 reads (13%) | called by muse, mutect2, varscan2
- OOSP2 | c.*734C>T | 3'UTR (SNP) | VAF 33/123 reads (27%) | catalogued as rs906311183; called by muse, mutect2, varscan2
- OR2J2 | c.-17-189G>A | Intron (SNP) | VAF 29/42 reads (69%) | called by muse, mutect2, varscan2
- OR5K2 | chr3:98501387 T>C | 3'Flank (SNP) | VAF 28/262 reads (11%) | catalogued as rs1445676878; called by muse, mutect2, varscan2
- OTUD6B | c.*288C>G | 3'UTR (SNP) | VAF 5/103 reads (5%) | called by muse, mutect2
- PDCD6 | c.-19C>T | 5'UTR (SNP) | VAF 16/135 reads (12%) | catalogued as rs1309633694; called by muse, mutect2, varscan2
- PDE5A | c.-19G>T | 5'UTR (SNP) | VAF 35/268 reads (13%) | called by muse, mutect2, varscan2
- PDE7B | c.*1513T>A | 3'UTR (SNP) | VAF 15/91 reads (16%) | called by muse, mutect2, varscan2
- PEX11B | c.*182G>A | 3'UTR (SNP) | VAF 17/42 reads (40%) | called by muse, mutect2, varscan2
- PIWIL4 | c.*273A>T | 3'UTR (SNP) | VAF 13/95 reads (14%) | catalogued as COSV54410175; called by muse, mutect2, varscan2
- PLK2 | chr5:58460100 C>T | 5'Flank (SNP) | VAF 52/140 reads (37%) | called by muse, varscan2
- PLK2 | chr5:58460103 C>T | 5'Flank (SNP) | VAF 50/136 reads (37%) | called by muse, varscan2
- PLXNA4 | c.*1222C>T | 3'UTR (SNP) | VAF 15/165 reads (9%) | called by muse, mutect2
- PMP2 | c.*2312G>A | 3'UTR (SNP) | VAF 5/97 reads (5%) | called by muse, mutect2
- POU2F3 | c.*423G>A | 3'UTR (SNP) | VAF 12/98 reads (12%) | called by muse, mutect2, varscan2
- PPP1CB | c.-88+40C>T | Intron (SNP) | VAF 5/62 reads (8%) | catalogued as rs1320977268; called by muse, mutect2
- PPP1R3F | c.*590C>T | 3'UTR (SNP) | VAF 6/89 reads (7%) | called by muse, mutect2
- PPP4R3A | chr14:91510186 G>A | 5'Flank (SNP) | VAF 42/293 reads (14%) | called by muse, mutect2, varscan2
- PRDM16 | c.*4557G>A | 3'UTR (SNP) | VAF 31/99 reads (31%) | called by muse, mutect2, varscan2
- PREX2 | c.*3178G>C | 3'UTR (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2
- PRRG2 | c.86-60C>G | Intron (SNP) | VAF 20/60 reads (33%) | called by muse, mutect2, varscan2
- PSTPIP1 | c.741+10G>A | Intron (SNP) | VAF 6/148 reads (4%) | called by muse, mutect2
- PTP4A1 | c.*462G>A | 3'UTR (SNP) | VAF 25/83 reads (30%) | called by muse, mutect2, varscan2
- RAB11FIP4 | c.*4102G>A | 3'UTR (SNP) | VAF 61/131 reads (47%) | called by muse, mutect2, varscan2
- RAI14 | c.*292C>T | 3'UTR (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- RB1CC1 | c.-497G>A | 5'UTR (SNP) | VAF 25/97 reads (26%) | catalogued as rs1204295033; called by muse, mutect2, varscan2
- RBBP4 | c.*1935A>G | 3'UTR (SNP) | VAF 61/123 reads (50%) | catalogued as rs969529076; called by muse, mutect2, varscan2
- RCOR1 | c.-212G>A | 5'UTR (SNP) | VAF 34/147 reads (23%) | catalogued as rs1254257076; called by muse, mutect2, varscan2
- RHOBTB3 | c.-323G>A | 5'UTR (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2
- RMND5B | c.695-96C>T | Intron (SNP) | VAF 16/25 reads (64%) | called by muse, mutect2, varscan2
- RNF7 | c.*1891G>A | 3'UTR (SNP) | VAF 11/270 reads (4%) | called by muse, mutect2
- RPL4 | c.-29G>A | 5'UTR (SNP) | VAF 99/303 reads (33%) | catalogued as rs542888621, COSV57178697; called by muse, mutect2, varscan2
- RTN2 | c.1451-12C>A | Intron (SNP) | VAF 27/205 reads (13%) | called by muse, mutect2, varscan2
- RTP1 | c.272+39C>T | Intron (SNP) | VAF 12/55 reads (22%) | called by muse, mutect2, varscan2
- RWDD1 | c.*4506A>C | 3'UTR (SNP) | VAF 16/67 reads (24%) | called by muse, mutect2, varscan2
- SAP30L | c.-539G>A | 5'UTR (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- SCN11A | c.-445C>T | 5'UTR (SNP) | VAF 62/213 reads (29%) | called by muse, mutect2, varscan2
- SCN9A | c.*3120T>C | 3'UTR (SNP) | VAF 44/81 reads (54%) | called by muse, mutect2, varscan2
- SEMA4C | c.1672+32G>A | Intron (SNP) | VAF 13/132 reads (10%) | called by muse, mutect2
- SEMA5A | c.*6969T>C | 3'UTR (SNP) | VAF 21/47 reads (45%) | called by muse, mutect2, varscan2
- SEMA6A | c.*897G>C | 3'UTR (SNP) | VAF 14/160 reads (9%) | catalogued as rs1174626014; called by muse, mutect2
- SESTD1 | c.*3429G>C | 3'UTR (SNP) | VAF 33/69 reads (48%) | called by muse, mutect2, varscan2
- SETD9 | chr5:56909302 G>A | 5'Flank (SNP) | VAF 38/115 reads (33%) | called by muse, mutect2, varscan2
- SHH | c.*1888C>T | 3'UTR (SNP) | VAF 20/323 reads (6%) | catalogued as rs991538189; called by muse, mutect2
- SLC25A27 | c.*364C>A | 3'UTR (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- SLC7A1 | c.*1513C>T | 3'UTR (SNP) | VAF 9/76 reads (12%) | called by muse, mutect2, varscan2
- SLIT3 | c.*630C>T | 3'UTR (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- SMAD4 | c.*5279G>C | 3'UTR (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2, varscan2
- SMARCB1 | chr22:23836815 C>T | 3'Flank (SNP) | VAF 18/32 reads (56%) | called by muse, mutect2, varscan2
- SMG1 | c.*1294G>A | 3'UTR (SNP) | VAF 8/76 reads (11%) | called by muse, mutect2, varscan2
- SMOC2 | c.*659C>G | 3'UTR (SNP) | VAF 5/126 reads (4%) | called by muse, mutect2
- SNAI3 | c.76+118G>A | Intron (SNP) | VAF 10/32 reads (31%) | called by muse, varscan2
- SNAP29 | c.*2375G>A | 3'UTR (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2, varscan2
- SNORD116-20 | n.32T>C | RNA (SNP) | VAF 125/234 reads (53%) | called by muse, mutect2, varscan2
- SNRNP25 | c.-81G>A | 5'UTR (SNP) | VAF 40/145 reads (28%) | catalogued as COSV51953633; called by muse, mutect2
- SORD2P | n.2217G>A | RNA (SNP) | VAF 75/268 reads (28%) | called by muse, mutect2, varscan2
- SP100 | c.-1G>A | 5'UTR (SNP) | VAF 72/189 reads (38%) | called by muse, mutect2, varscan2
- SPATA17 | c.724-13C>G | Intron (SNP) | VAF 16/147 reads (11%) | called by mutect2, varscan2
- SREBF1 | c.3103-13T>A | Intron (SNP) | VAF 9/152 reads (6%) | called by muse, mutect2
- SRGAP3 | c.*215C>T | 3'UTR (SNP) | VAF 50/149 reads (34%) | called by muse, mutect2, varscan2
- SRPK1 | c.13+49G>A | Intron (SNP) | VAF 7/105 reads (7%) | catalogued as COSV60411923; called by muse, mutect2
- SSPOP | n.8669C>T | RNA (SNP) | VAF 17/223 reads (8%) | called by muse, mutect2
- STAT1 | c.*145G>A | 3'UTR (SNP) | VAF 16/242 reads (7%) | called by muse, mutect2
- STIL | c.*546G>T | 3'UTR (SNP) | VAF 9/27 reads (33%) | catalogued as rs930424060; called by muse, varscan2
- SVOP | c.*221G>A | 3'UTR (SNP) | VAF 11/200 reads (6%) | called by muse, mutect2
- TAF1 | c.2164-52G>C | Intron (SNP) | VAF 9/114 reads (8%) | called by muse, mutect2
- TAFA5 | c.*79G>A | 3'UTR (SNP) | VAF 38/69 reads (55%) | called by muse, mutect2, varscan2
- TASOR | chr3:56621847 C>T | 3'Flank (SNP) | VAF 30/61 reads (49%) | called by muse, mutect2, varscan2
- TBC1D8B | c.*1932G>C | 3'UTR (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
- THNSL2 | chr2:88172702 G>A | 5'Flank (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- THRA | c.*353C>T | 3'UTR (SNP) | VAF 15/146 reads (10%) | called by muse, mutect2, varscan2
- TMEM201 | c.1160+197C>T | Intron (SNP) | VAF 100/177 reads (56%) | catalogued as rs962763733; called by muse, mutect2, varscan2
- TMEM80 | c.460+432G>C | Intron (SNP) | VAF 16/327 reads (5%) | called by muse, mutect2
- TNFAIP8 | c.-38G>A | 5'UTR (SNP) | VAF 10/251 reads (4%) | catalogued as rs937421978; called by muse, mutect2
- TNRC6B | c.*5136G>C | 3'UTR (SNP) | VAF 6/157 reads (4%) | called by muse, mutect2
- TRHDE | c.*255C>T | 3'UTR (SNP) | VAF 11/95 reads (12%) | called by muse, mutect2, varscan2
- TRIO | c.1368+12G>C | Intron (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2, varscan2
- TRPM7 | c.2988+12G>A | Intron (SNP) | VAF 28/358 reads (8%) | catalogued as rs756758024; called by muse, mutect2
- TXNL1 | chr18:56638596 G>A | 5'Flank (SNP) | VAF 12/55 reads (22%) | catalogued as rs1391331465; called by muse, mutect2, varscan2
- UBXN7 | c.*3278G>C | 3'UTR (SNP) | VAF 9/67 reads (13%) | called by muse, mutect2, varscan2
- VPS13A | c.*689C>T | 3'UTR (SNP) | VAF 32/98 reads (33%) | catalogued as rs1038987808; called by muse, mutect2, varscan2
- VPS26A | c.*1406G>A | 3'UTR (SNP) | VAF 6/54 reads (11%) | catalogued as COSV54966725; called by muse, mutect2, varscan2
- VPS8 | c.1735-3679G>A | Intron (SNP) | VAF 7/65 reads (11%) | catalogued as rs1268270449; called by muse, mutect2
- VSX1 | chr20:25071891 G>C | 3'Flank (SNP) | VAF 27/72 reads (38%) | called by muse, mutect2, varscan2
- WBP4 | c.-149G>C | 5'UTR (SNP) | VAF 25/93 reads (27%) | catalogued as rs760951408; called by muse, mutect2, varscan2
- WDR11 | c.-18C>G | 5'UTR (SNP) | VAF 15/100 reads (15%) | called by muse, mutect2, varscan2
- XKR6 | c.764+76178C>T | Intron (SNP) | VAF 16/172 reads (9%) | called by muse, mutect2
- XYLT2 | c.*776C>T | 3'UTR (SNP) | VAF 9/196 reads (5%) | called by muse, mutect2
- ZFAND5 | c.*3225G>A | 3'UTR (SNP) | VAF 7/81 reads (9%) | called by muse, mutect2
- ZMAT4 | c.*747T>G | 3'UTR (SNP) | VAF 54/127 reads (43%) | called by muse, mutect2, varscan2
